TCGA case TCGA-EE-A184 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a8cfea5-1dcd-4dbb-bbd9-5bb602c54922

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 72 years; Vital status: Dead; Days to death: 2,073 days (5.7 years).

Diagnoses (8)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.6; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of upper limb and shoulder; Classification of tumor: metastasis; Age at diagnosis: 77.7 years (28,364 days); Days to diagnosis: 1,917 days (5.2 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.4 years (26,447 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Classification of tumor: Prior primary.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Upper limb, NOS. Age at diagnosis: 76.0 years (27,756 days); Days to diagnosis: 1,309 days (3.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,344 days (3.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Upper limb, NOS. Age at diagnosis: 76.3 years (27,875 days); Days to diagnosis: 1,428 days (3.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,428 days (3.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
7. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 76.6 years (27,973 days); Days to diagnosis: 1,526 days (4.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,526 days (4.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
8. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Upper limb, NOS. Age at diagnosis: 76.6 years (27,973 days); Days to diagnosis: 1,526 days (4.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,526 days (4.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 1,309 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 1,309 days (3.6 years).
- Day 1,428 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 1,428 days (3.9 years).
- Day 1,526 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 1,526 days (4.2 years).
- Day 1,526 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 1,526 days (4.2 years).
- Follow-up contact recording only the day: day 2,073.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A184-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A184-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 410 mg.
  Slide TCGA-EE-A184-06A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A184-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Breslow thickness at diagnosis: 1.95; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 2; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: Right wrist; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Rectum; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior adenocarcinoma of the rectum. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,073 days; disease-specific survival: event status not recorded, 2,073 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,309 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A184-06A-11D-A194-01): tumor purity 0.85, ploidy 2.27, whole-genome doublings 0.
